Somatic mutation profile of tumor specimen TCGA-EL-A4K1-01A (aliquot TCGA-EL-A4K1-01A-11D-A257-08) from TCGA case TCGA-EL-A4K1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 68.0 years (24,846 days).
Specimen TCGA-EL-A4K1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 894fdbc7-e2f9-40e8-98ad-d327ea49b71e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K1-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K1-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66acdf06-65f6-4ac7-abb1-97a1ddadb9ca

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABO | c.815C>G p.S272W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782721438, COSV101505925, COSV71743460; called by muse, mutect2
- ATRX | c.5140G>T p.D1714Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969947; called by muse, mutect2, varscan2
- CACNA1D | c.4523T>A p.L1508Q (on ENST00000350061 / NM_001128840.3; = p.L1528Q on NM_000720.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99856468; called by muse, mutect2, varscan2
- TBC1D32 | c.2480T>C p.I827T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs764743693, COSV99249396; called by muse, varscan2
- CYC1 | c.189G>A p.A63= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs146030978; called by muse, mutect2, varscan2
- DENND2B | c.1419C>T p.N473= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs768432788, COSV100567088; called by muse, mutect2, varscan2
